Somatic mutation profile of tumor specimen CUPP-B52G-TTM1-A (aliquot CUPP-B52G-TTM1-A-1-0-D-A82Z-47) from CCG case CUPP-B52G, project CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, metastatic, NOS; Tissue or organ of origin: Unknown primary site; Age at diagnosis: 68.6 years (25,062 days).
Specimen CUPP-B52G-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29c1a939-a85c-4ad4-a3e0-8545f938442f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CUPP-B52G-NT1-A (Solid Tissue Normal), aliquot CUPP-B52G-NT1-A-1-0-D-A82Z-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad58e2e3-6764-4002-bf66-601125802c0f

The open-access MAF lists 193 somatic variants for this specimen: 116 protein-altering or splice-affecting, 70 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 108, Silent 70, Nonsense Mutation 8, 5'UTR 3, Intron 3, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC011455.2 | c.1228C>T p.R410W | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs765803456; called by mutect2, varscan2
- AC132217.2 | c.101C>A p.A34E | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.166); catalogued as rs756776069; called by mutect2, varscan2
- ADPRHL1 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV60260501; called by mutect2, varscan2
- AMER2 | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.134); catalogued as COSV63439405; called by mutect2, varscan2
- ANAPC2 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs374836035; called by muse, varscan2
- ANGPT1 | c.1268C>A p.A423D | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV52431677; called by mutect2, varscan2
- ANGPT1 | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.07); catalogued as COSV104399208; called by mutect2, varscan2
- AP4S1 | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV53554568; called by muse, mutect2, varscan2
- CARF | c.2111C>T p.P704L | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.656); catalogued as COSV57548427; called by muse, mutect2, varscan2
- CASKIN2 | c.2930C>A p.P977H | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.319); catalogued as rs751934298; called by muse, mutect2, varscan2
- CDH10 | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.14); catalogued as COSV100051463, COSV52569250; called by mutect2, varscan2
- CFAP77 | c.929G>A p.G310E | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100545489; called by mutect2, varscan2
- CILP | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.06); catalogued as rs760076237, COSV56028605; called by mutect2, varscan2
- CNTROB | c.2095C>G p.Q699E | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.006); catalogued as rs760140158; called by muse, mutect2, varscan2
- DCHS1 | c.6062G>A p.R2021H | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs141121553; called by muse, mutect2, varscan2
- DISP3 | c.2929G>A p.V977M | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.078); catalogued as rs778432547, COSV53838361; called by mutect2, varscan2
- DPYSL5 | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as rs535536473; called by mutect2, varscan2
- EDIL3 | c.1153C>T p.P385S | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.574); catalogued as COSV99678334; called by mutect2, varscan2
- EIF4EBP2 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1315957727; called by muse, mutect2, varscan2
- EMC8 | c.134G>C p.G45A | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs777977232; called by muse, mutect2, varscan2
- FMN2 | c.2893C>T p.P965S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.036); catalogued as rs566178478; called by mutect2, varscan2
- FOXR2 | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369953733, COSV100189411, COSV59258041; called by mutect2, varscan2
- GNS | c.179T>A p.V60E | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV50693922; called by mutect2, varscan2
- HOGA1 | c.976T>G p.W326G | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs761995486; called by mutect2, varscan2
- INF2 | c.2134C>T p.P712S | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs759153097; called by mutect2, varscan2
- KCNK2 | c.907G>C p.V303L (on ENST00000444842 / NM_001017425.3; = p.V288L on NM_014217.4) | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.302); catalogued as COSV67208287; called by mutect2, varscan2
- KIAA1109 | c.11153G>A p.R3718Q | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.462); catalogued as rs746735957, COSV52684859; called by mutect2, varscan2
- KMT2E | c.5147C>T p.P1716L | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); catalogued as rs1466598364; called by muse, mutect2, varscan2
- LRWD1 | c.1663G>A p.A555T | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as rs1356027610; called by muse, mutect2, varscan2
- MAGEB4 | c.365A>G p.Y122C | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.056); catalogued as COSV66776253; called by mutect2, varscan2
- MAST1 | c.3580G>A p.A1194T | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as rs200847431; called by mutect2, varscan2
- MDC1 | c.2669T>C p.L890S | Missense Mutation (SNP) | VAF 32/242 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs1250207757; called by mutect2, varscan2
- MLF1 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.834); catalogued as rs201952489, COSV63032290; called by mutect2, varscan2
- MSN | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.562); catalogued as rs1310782775; called by mutect2, varscan2
- MUC17 | c.5462C>T p.A1821V | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.348); catalogued as rs367815935; called by mutect2, varscan2
- MUC22 | c.3751G>A p.E1251K | Missense Mutation (SNP) | VAF 72/349 reads (21%) | SIFT tolerated (0.63); catalogued as rs200777418; called by muse, varscan2
- MUC4 | c.1799C>T p.P600L | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.722); catalogued as rs761632323, COSV62145723; called by mutect2, varscan2
- MYO7A | c.3226G>A p.E1076K | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.737); catalogued as COSV104433815; called by muse, mutect2, varscan2
- NEK1 | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71455933; called by mutect2, varscan2
- NOD2 | c.238C>A p.P80T | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.783); catalogued as rs370734707; called by mutect2, varscan2
- OR1P1 | c.616C>A p.Q206K | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs572936462; called by muse, varscan2
- OTUD3 | c.1135A>G p.S379G | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.169); catalogued as rs201731406; called by mutect2, varscan2
- PAGE4 | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.753); catalogued as rs781806435; called by muse, mutect2, varscan2
- PGBD1 | c.1624T>C p.Y542H | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs1204976453; called by mutect2, varscan2
- PHF13 | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 8/96 reads (8%) | catalogued as COSV50010600, COSV99275529; called by mutect2, varscan2
- PSEN2 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100423240; called by mutect2, varscan2
- PTPN22 | c.1744G>A p.D582N (on ENST00000359785 / NM_001193431.2; = p.D527N on NM_012411.5) | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.073); catalogued as rs753550291; called by muse, mutect2, varscan2
- RABGGTB | c.50C>T p.T17I | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.152); catalogued as rs760027784; called by muse, mutect2, varscan2
- RNF34 | c.705A>T p.E235D | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs61751317; called by muse, varscan2
- ROM1 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs779471039; called by muse, mutect2, varscan2
- SLC4A4 | c.1276G>A p.G426R (on ENST00000264485 / NM_001098484.3; = p.G382R on NM_003759.4) | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.806); catalogued as rs760529597, COSV52625372; called by mutect2, varscan2
- SLITRK5 | c.1966G>A p.G656R | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.027); catalogued as COSV61522481; called by mutect2, varscan2
- SPTBN5 | c.7381A>G p.K2461E | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as rs369936657; called by mutect2, varscan2
- SRCIN1 | c.3232G>A p.E1078K (on ENST00000621492; = p.E1044K on NM_025248.3) | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs538606834; called by muse, mutect2, varscan2
- TARS1 | c.1429A>G p.K477E | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.049); catalogued as rs749683651; called by mutect2, varscan2
- TNFRSF13B | c.559A>T p.K187* | Nonsense Mutation (SNP) | VAF 12/90 reads (13%) | catalogued as rs1394047401; called by mutect2, varscan2
- TNFRSF8 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1028584203; called by muse, mutect2, varscan2
- TNKS1BP1 | c.4432C>T p.L1478F | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.571); catalogued as rs1367921103; called by mutect2, varscan2
- TOR1AIP1 | c.1436A>G p.H479R | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1274832609; called by muse, mutect2, varscan2
- TRHDE | c.353G>A p.G118E | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1332394880; called by mutect2, varscan2
- TSSK4 | c.556C>G p.R186G | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs188911161; called by muse, mutect2, varscan2
- ZBED4 | c.2158C>T p.L720F | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1170691920; called by mutect2, varscan2
- ZDBF2 | c.373C>T p.Q125* | Nonsense Mutation (SNP) | VAF 15/138 reads (11%) | catalogued as COSV65624354; called by mutect2, varscan2
- ZNF334 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs202007181; called by muse, mutect2, varscan2
- ZNF514 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.807); catalogued as rs375276324; called by mutect2, varscan2
- ZNF804B | c.2962G>A p.E988K | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60828893; called by mutect2, varscan2
- ACOX3 | c.1327G>A p.D443N | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- AGBL4 | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- AL590132.1 | c.1272G>A p.W424* | Nonsense Mutation (SNP) | VAF 14/81 reads (17%) | called by mutect2, varscan2
- CFAP57 | c.2048T>G p.F683C | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.065); called by mutect2, varscan2
- COL11A2 | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 26/244 reads (11%) | called by muse, varscan2
- COL28A1 | c.784A>C p.K262Q | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- COL4A6 | c.4136C>T p.P1379L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); called by mutect2, varscan2
- CYBB | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); called by mutect2, varscan2
- DENND2B | c.359G>A p.G120D | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); called by mutect2, varscan2
- ERC1 | c.164C>T p.S55L | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- ERGIC3 | c.662G>A p.S221N | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, varscan2
- EXO1 | c.2080C>T p.Q694* | Nonsense Mutation (SNP) | VAF 10/58 reads (17%) | called by mutect2, varscan2
- FBRSL1 | c.2443G>A p.A815T | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.225); called by mutect2, varscan2
- FOXR2 | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by mutect2, varscan2
- GATA1 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.264); called by muse, varscan2
- GATA3 | c.177C>A p.H59Q | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- GGT6 | c.1393C>T p.Q465* (on ENST00000574154 / NM_001122890.3; = p.Q433* on NM_153338.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 20/116 reads (17%) | called by mutect2, varscan2
- GPR135 | c.1043G>A p.C348Y | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by mutect2, varscan2
- GPR174 | c.318C>G p.I106M | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- IGF2BP2 | c.1402G>A p.G468S | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.023); called by muse, varscan2
- ITIH5 | c.2165G>A p.G722E | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- JPT2 | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.23); called by muse, mutect2
- MALRD1 | c.245T>A p.M82K | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.345); called by mutect2, varscan2
- MEGF10 | c.751G>A p.G251R | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by mutect2, varscan2
- MEGF10 | c.752G>A p.G251E | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- MYO5B | c.5154G>T p.Q1718H | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.599); called by mutect2, varscan2
- N4BP3 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.021); called by mutect2, varscan2
- NBEA | c.8827C>G p.Q2943E | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.318); called by mutect2, varscan2
- NDST2 | c.1861T>G p.F621V | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- NDUFB4 | c.262C>A p.L88I | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.205); called by mutect2, varscan2
- NES | c.3451G>A p.G1151R | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by mutect2, varscan2
- NYX | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.012); called by mutect2, varscan2
- OR14A2 | c.402G>A p.M134I | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); called by mutect2, varscan2
- PEG3 | c.943A>T p.M315L | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); called by mutect2, varscan2
- PIK3R5 | c.2303C>T p.S768F | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- PRICKLE3 | c.1750G>A p.A584T | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by mutect2, varscan2
- PRRT1 | c.734A>G p.K245R | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- RAB26 | c.704A>G p.E235G | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SIRT7 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- SPATS1 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.037); called by mutect2, varscan2
- TBC1D14 | c.780G>A p.W260* | Nonsense Mutation (SNP) | VAF 25/141 reads (18%) | called by muse, mutect2, varscan2
- THOP1 | c.940C>A p.L314M | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- TJP2 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by mutect2, varscan2
- TOGARAM2 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.019); called by mutect2, varscan2
- TRPV3 | c.1846A>C p.N616H | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBE2U | c.314T>G p.L105W | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- VRTN | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by mutect2, varscan2
- YBX3 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.137); called by mutect2, varscan2
- ZDHHC7 | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.056); called by mutect2, varscan2
- ZNF331 | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ACBD5 | c.780C>T p.G260= (on ENST00000375888 / NM_001352568.1; = p.G251= on NM_145698.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 35/159 reads (22%) | catalogued as rs141431716; called by muse, mutect2, varscan2
- ADGB | c.1617A>G p.P539= | Silent (SNP) | VAF 20/91 reads (22%) | catalogued as rs539123524; called by muse, mutect2, varscan2
- AGAP3 | c.2538G>A p.E846= (on ENST00000622464; = p.E882= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/91 reads (19%) | called by mutect2, varscan2
- ANO3 | c.2800C>T p.L934= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as rs778690266; called by mutect2, varscan2
- APOE | c.672G>A p.R224= | Silent (SNP) | VAF 10/60 reads (17%) | called by mutect2, varscan2
- ARMC5 | c.1155A>G p.A385= | Silent (SNP) | VAF 20/104 reads (19%) | catalogued as rs752777691; called by muse, mutect2, varscan2
- BRINP1 | c.228C>T p.A76= | Silent (SNP) | VAF 8/62 reads (13%) | called by mutect2, varscan2
- C15orf39 | c.651T>C p.Y217= | Silent (SNP) | VAF 21/119 reads (18%) | catalogued as rs369281067; called by muse, mutect2, varscan2
- C1orf131 | c.571C>T p.L191= | Silent (SNP) | VAF 8/84 reads (10%) | called by mutect2, varscan2
- C2orf16 | c.1170G>A p.G390= | Silent (SNP) | VAF 18/151 reads (12%) | catalogued as rs1203845020; called by muse, mutect2, varscan2
- C7 | c.2052G>A p.K684= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as rs771866199; called by mutect2, varscan2
- CDHR4 | c.537A>G p.G179= | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as rs1407945382; called by muse, mutect2, varscan2
- CDK13 | c.279G>A p.A93= | Silent (SNP) | VAF 12/65 reads (18%) | called by mutect2, varscan2
- CFAP161 | c.268C>T p.L90= | Silent (SNP) | VAF 10/75 reads (13%) | called by mutect2, varscan2
- CGAS | c.783T>A p.P261= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as rs775885294; called by mutect2, varscan2
- CTNND2 | c.2580A>C p.P860= | Silent (SNP) | VAF 10/72 reads (14%) | called by mutect2, varscan2
- CUL7 | c.2526G>A p.E842= | Silent (SNP) | VAF 14/128 reads (11%) | catalogued as COSV99538821, COSV99539486; called by mutect2, varscan2
- DMXL1 | c.2082A>G p.A694= | Silent (SNP) | VAF 30/158 reads (19%) | catalogued as rs751367808, COSV100223714; called by muse, varscan2
- EFCC1 | c.777G>A p.Q259= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs1009875461; called by mutect2, varscan2
- EIF1B | c.153A>G p.A51= | Silent (SNP) | VAF 32/125 reads (26%) | catalogued as rs371724665; called by muse, mutect2, varscan2
- EPB41L3 | c.3030A>C p.T1010= | Silent (SNP) | VAF 23/105 reads (22%) | catalogued as rs753306885; called by muse, mutect2, varscan2
- EPB41L4B | c.1620C>T p.S540= | Silent (SNP) | VAF 6/50 reads (12%) | called by mutect2, varscan2
- FAM205C | c.675G>A p.E225= | Silent (SNP) | VAF 7/72 reads (10%) | called by mutect2, varscan2
- FBXW9 | c.867C>T p.T289= | Silent (SNP) | VAF 8/58 reads (14%) | called by mutect2, varscan2
- FNDC3B | c.2187C>T p.T729= | Silent (SNP) | VAF 23/116 reads (20%) | catalogued as rs150745433, COSV61049825; called by muse, mutect2, varscan2
- GGT2 | c.627C>G p.T209= | Silent (SNP) | VAF 25/101 reads (25%) | catalogued as rs759602417; called by muse, mutect2, varscan2
- GGT6 | c.1392C>T p.G464= (on ENST00000574154 / NM_001122890.3; = p.G432= on NM_153338.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/117 reads (17%) | catalogued as rs1164988897; called by mutect2, varscan2
- H3C13 | c.285G>A p.E95= | Silent (SNP) | VAF 30/158 reads (19%) | called by mutect2, varscan2
- IRS4 | c.372C>G p.A124= | Silent (SNP) | VAF 8/36 reads (22%) | called by mutect2, varscan2
- KBTBD11 | c.201C>T p.S67= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as rs776723854; called by mutect2, varscan2
- LRP1 | c.10581C>T p.P3527= | Silent (SNP) | VAF 7/45 reads (16%) | called by mutect2, varscan2
- MAP1B | c.4720C>T p.L1574= | Silent (SNP) | VAF 16/112 reads (14%) | called by mutect2, varscan2
- MDK | c.279G>A p.A93= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as rs764089666, COSV58988000; called by muse, mutect2, varscan2
- MOGS | c.1782C>T p.T594= | Silent (SNP) | VAF 22/109 reads (20%) | catalogued as rs762635961; called by muse, mutect2, varscan2
- MYH7 | c.2607C>T p.R869= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as rs1365184293, COSV62525899; called by mutect2, varscan2
- MYO7A | c.3855C>T p.N1285= | Silent (SNP) | VAF 24/116 reads (21%) | catalogued as rs750763506; called by muse, mutect2, varscan2
- NES | c.2316G>A p.Q772= | Silent (SNP) | VAF 14/124 reads (11%) | catalogued as COSV100957891; called by mutect2, varscan2
- NLRP11 | c.1452A>G p.Q484= | Silent (SNP) | VAF 25/97 reads (26%) | catalogued as rs759333340; called by muse, mutect2, varscan2
- NUP133 | c.2569C>T p.L857= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as rs372600439; called by mutect2, varscan2
- NUP205 | c.2241C>T p.F747= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as COSV53664553; called by mutect2, varscan2
- NUP85 | c.1695G>A p.T565= | Silent (SNP) | VAF 37/142 reads (26%) | catalogued as rs758258054; called by muse, mutect2, varscan2
- NXPH4 | c.255G>A p.A85= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as rs376307852; called by mutect2, varscan2
- OASL | c.594C>T p.F198= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs759301773, COSV57477529; called by mutect2, varscan2
- PCDHGA5 | c.2325C>T p.Y775= | Silent (SNP) | VAF 23/129 reads (18%) | catalogued as rs761615702, COSV53901345; called by mutect2, varscan2
- PHACTR4 | c.1890G>A p.R630= (on ENST00000373839 / NM_001350159.2; = p.R640= on NM_023923.4) | Silent (SNP) | VAF 28/107 reads (26%) | catalogued as rs776684868; called by muse, mutect2, varscan2
- PKD1 | c.5913G>A p.V1971= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as rs200626823, CD1210687; called by mutect2, varscan2
- PLEKHG1 | c.1053G>A p.T351= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as rs148074221; called by mutect2, varscan2
- PLEKHG1 | c.2025G>A p.K675= | Silent (SNP) | VAF 8/76 reads (11%) | called by mutect2, varscan2
- PRRC2B | c.4878G>A p.E1626= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as rs996148234; called by muse, mutect2, varscan2
- PYHIN1 | c.486C>T p.S162= | Silent (SNP) | VAF 16/112 reads (14%) | called by mutect2, varscan2
- RIF1 | c.3408G>A p.T1136= | Silent (SNP) | VAF 7/75 reads (9%) | catalogued as rs770348913, COSV54617487, COSV99691468; called by mutect2, varscan2
- RSPH3 | c.1206G>A p.Q402= (on ENST00000252655; = p.Q260= on NM_031924.8) | Silent (SNP) | VAF 43/169 reads (25%) | catalogued as rs779361922; called by muse, mutect2, varscan2
- SKOR2 | c.2088G>A p.P696= | Silent (SNP) | VAF 6/40 reads (15%) | called by mutect2, varscan2
- SLC22A13 | c.795C>T p.F265= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as rs1408631688; called by mutect2, varscan2
- SLC45A2 | c.1572C>T p.L524= | Silent (SNP) | VAF 21/172 reads (12%) | catalogued as rs757597359, COSV56874983; called by muse, mutect2, varscan2
- SPEG | c.1089C>T p.P363= | Silent (SNP) | VAF 18/98 reads (18%) | catalogued as rs1192939303; called by mutect2, varscan2
- SPTA1 | c.6966C>T p.F2322= | Silent (SNP) | VAF 15/95 reads (16%) | called by muse, varscan2
- TAS2R16 | c.195G>A p.L65= | Silent (SNP) | VAF 12/82 reads (15%) | called by mutect2, varscan2
- TBC1D30 | c.2130G>A p.G710= (on ENST00000542120; = p.G547= on NM_015279.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/129 reads (13%) | catalogued as COSV57483263; called by muse, mutect2, varscan2
- TCF3 | c.165C>T p.S55= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV99513521; called by mutect2, varscan2
- TENM2 | c.3741C>T p.I1247= (on ENST00000518659 / NM_001122679.2; = p.I1015= on NM_001080428.3) | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as rs376888998; called by mutect2, varscan2
- TIFAB | c.258C>G p.V86= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as rs374245577; called by mutect2, varscan2
- TMEM104 | c.1026C>T p.F342= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as rs562626910, COSV59108758, COSV59109202; called by mutect2, varscan2
- TMEM174 | c.504C>T p.T168= | Silent (SNP) | VAF 12/83 reads (14%) | called by mutect2, varscan2
- TNRC18 | c.3408C>T p.S1136= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as rs1487673612; called by mutect2, varscan2
- TRAF1 | c.552G>A p.E184= | Silent (SNP) | VAF 10/102 reads (10%) | called by mutect2, varscan2
- TRIM55 | c.69A>G p.Q23= | Silent (SNP) | VAF 10/112 reads (9%) | catalogued as rs1312624155; called by mutect2, varscan2
- TRIM67 | c.2322C>T p.N774= | Silent (SNP) | VAF 25/138 reads (18%) | catalogued as rs770312214; called by muse, mutect2, varscan2
- ZNF274 | c.1452T>C p.C484= (on ENST00000610905; = p.C379= on NM_016324.3) | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as rs368539115; called by muse, mutect2, varscan2
- ZNF668 | c.1068G>A p.L356= | Silent (SNP) | VAF 22/132 reads (17%) | catalogued as rs1567398158; called by mutect2, varscan2
- ATPAF1 | c.-13G>C | 5'UTR (SNP) | VAF 10/62 reads (16%) | called by mutect2, varscan2
- CMTR1 | c.-96G>C | 5'UTR (SNP) | VAF 16/82 reads (20%) | called by mutect2, varscan2
- GAL3ST1 | c.-120+1621C>T | Intron (SNP) | VAF 15/105 reads (14%) | catalogued as rs1019336747; called by muse, mutect2, varscan2
- SMAD4 | c.-108T>C | 5'UTR (SNP) | VAF 8/84 reads (10%) | called by mutect2, varscan2
- SNTG1 | c.810+15796G>A | Intron (SNP) | VAF 8/42 reads (19%) | called by mutect2, varscan2
- SPEF2 | c.4448-4175A>G | Intron (SNP) | VAF 17/123 reads (14%) | called by mutect2, varscan2
- TBC1D27P | n.3394G>A | RNA (SNP) | VAF 6/48 reads (13%) | catalogued as rs1041083845; called by mutect2, varscan2
